Somatic mutation profile of tumor specimen 0DQ80T from CCDI case PBCETZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,874 days).
Specimen 0DQ80T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a7d84d4-1e8b-47a9-9f86-dba2e04541d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7WG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9782552-24df-43da-a69a-ca3a355c8d39

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, 3'UTR 2, Intron 2, Splice Region 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 470/1103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112153542; called by muse, mutect2, varscan2
- C7 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 339/920 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs192439696; called by muse, mutect2, varscan2
- MYO5C | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 302/669 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766392804, COSV55911278; called by muse, mutect2, varscan2
- NPAS4 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 280/581 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs374933742; called by muse, mutect2, varscan2
- PLCL2 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 204/470 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.862); catalogued as rs1218641177; called by muse, mutect2, varscan2
- ZNF611 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 275/640 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312712011; called by muse, mutect2, varscan2
- CPNE8 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 288/811 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX8 | c.2344G>A p.G782S | Missense Mutation (SNP) | VAF 26/871 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH7 | c.11765-4T>C | Splice Region (SNP) | VAF 316/752 reads (42%) | called by muse, mutect2, varscan2
- FSD2 | c.2155C>T p.H719Y | Missense Mutation (SNP) | VAF 26/971 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- IDUA | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, varscan2
- PCOLCE | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 253/617 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- SMIM31 | c.131dup p.R46Kfs*9 | Frame Shift Ins (INS) | VAF 214/594 reads (36%) | called by mutect2, varscan2
- ALMS1 | c.1761G>A p.Q587= | Silent (SNP) | VAF 319/627 reads (51%) | catalogued as COSV100042908; called by muse, mutect2, varscan2
- NEURL1B | c.1551G>A p.T517= | Silent (SNP) | VAF 41/530 reads (8%) | catalogued as rs1048149668, COSV63940817; called by muse, mutect2
- PLPPR4 | c.1911G>A p.P637= | Silent (SNP) | VAF 433/1029 reads (42%) | catalogued as rs201385642, COSV100926892, COSV64567674; called by muse, mutect2, varscan2
- RHOT2 | c.894C>T p.S298= | Silent (SNP) | VAF 133/329 reads (40%) | called by muse, mutect2, varscan2
- SCAP | c.1785C>T p.G595= | Silent (SNP) | VAF 268/629 reads (43%) | catalogued as rs1245509204; called by muse, varscan2
- TOPAZ1 | c.4333C>T p.L1445= | Silent (SNP) | VAF 277/644 reads (43%) | called by muse, mutect2, varscan2
- ZNF521 | c.1914A>G p.Q638= | Silent (SNP) | VAF 248/538 reads (46%) | catalogued as rs1254113176; called by muse, mutect2, varscan2
- C1QL4 | c.*10G>A | 3'UTR (SNP) | VAF 141/356 reads (40%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- GABRG1 | c.-22C>T | 5'UTR (SNP) | VAF 264/741 reads (36%) | called by muse, mutect2, varscan2
- IREB2 | c.19+87C>T | Intron (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- MUC12 | c.*6C>T | 3'UTR (SNP) | VAF 160/398 reads (40%) | catalogued as rs1054248796; called by muse, mutect2, varscan2
